Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8686, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8686-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]	Case ID	[REDACTED]	Microscopic Description	Diagnosis Details
[REDACTED]	[REDACTED]	In lesser curvature, there is an enlarged ulcerated tumor occupying lumen, with 10x8x3cm in size, firm and gray surface.	Tumor is invasion into serosa. Tumor is composed of cords or trabeculae or arranging in diffuse or adenoids. Mitotic index is present. Nuclei are hyperchromatic and irregularly enlarged and prominent nucleoli. Cytoplasm are scant and eosinophilic. Stroma is invasion of prominent lymphocytes.	Adenocarcinoma, poorly-differentiated, infiltrating serosa

[page 2 of 3]
Comments	Formatted Path Report
	STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Antrum Tumor size: 10 x 8 x 3 cm Tumor features: Ulcerated Histologic type: Tubular adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Serosa (visceral peritoneum) Lymph nodes: 2/2 positive for metastasis (Adjacent lymph node 2/2) Lymphatic invasion: Present Venous invasion: Not specified Perineural invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

Ica ID

[page 3 of 3]
Excision date

[REDACTED]

Excision date

Source: NCI Genomic Data Commons file 114477af-5bc7-471e-904b-aa52f84240e6 (TCGA-BR-8686.269BC522-3673-4A1C-8B0E-8EF1BDB8CDFF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).